Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5084, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5084-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: KIDNEY, RIGHT, RADICAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, UNCLASSIFIABLE (See Comment)
- B. FUHRMAN NUCLEAR GRADE IS 3-4.
- C. THERE IS EXTENSIVE NECROSIS.
- D. THE GREATEST DIAMETER OF THE NEOPLASM IS 8.2 cm.
- E. THE NEOPLASM EXTENDS INTO THE RENAL SINUS ADIPOSE TISSUE.
- F. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- G. FOCI SUSPICIOUS FOR ANGIOLYMPHATIC INVASION ARE IDENTIFIED.
- H. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- I. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- J. TNM STAGE: pT3a N1 MX.

PART 2: LYMPH NODE, HILAR, EXCISION-

- A. METASTATIC RENAL CELL CARCINOMA IN ONE (1) of ONE₂(1) LYMPH NODES WITH EXTRACAPSULAR EXTENSION.
- B. THE LYMPH NODE MEASURES 3.8 CM IN GREATEST DIMENSIONS AND IS COMPLETELY REPLACED BY METASTATIC CARCINOMA.

PART 3: ADRENAL GLAND, ADRENALECTOMY-

- A. UNREMARKABLE ADRENAL GLAND.
- B. NO EVIDENCE OF RENAL CELL CARCINOMA.

Source: NCI Genomic Data Commons file 57333340-f817-47bd-aae6-48a343226536 (TCGA-B0-5084.FA09A53E-5C53-4A61-9BC6-6393F045DDBC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).